Somatic mutation profile of tumor specimen TCGA-EA-A5FO-01A (aliquot TCGA-EA-A5FO-01A-21D-A28B-09) from TCGA case TCGA-EA-A5FO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 59.0 years (21,561 days).
Specimen TCGA-EA-A5FO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b92bd19-e3d4-40dd-bd53-3af901298d8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A5FO-10A (Blood Derived Normal), aliquot TCGA-EA-A5FO-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/460b6854-7156-4bb5-af9a-d9f064114284

The open-access MAF lists 88 somatic variants for this specimen: 66 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 53, Silent 22, Nonsense Mutation 4, Splice Site 3, Splice Region 2, Frame Shift Ins 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 47/193 reads (24%) | catalogued as rs878854383, CM098361, COSV55878807; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 79/174 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 65/67 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs121913478, CM960653, COSV60640350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 123/131 reads (94%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.2600T>A p.L867Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV57170222; called by muse, mutect2, varscan2
- ANAPC2 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs878889078, COSV100119248, COSV58808933; called by muse, mutect2, varscan2
- ARHGAP36 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as rs1378988123, COSV52271271; called by muse, mutect2, varscan2
- ATXN7L3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs1297279073, COSV66989658; called by muse, mutect2, varscan2
- BACH2 | c.1641_1643del p.S548del | In Frame Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs1562317674; called by pindel, varscan2
- BSCL2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs781147014, COSV54014794; called by muse, mutect2, varscan2
- CACNG7 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV55817075; called by muse, mutect2, varscan2
- CASK | c.1669-1G>A p.X557_splice | Splice Site (SNP) | VAF 39/120 reads (33%) | catalogued as COSV59374457; called by muse, mutect2, varscan2
- CHD6 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58561800; called by muse, mutect2, varscan2
- CLEC14A | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs1236628033, COSV60561689; called by muse, mutect2, varscan2
- CNKSR1 | c.1436C>A p.P479H (on ENST00000374253 / NM_001297647.2; = p.P472H on NM_006314.3) | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58794501; called by muse, mutect2, varscan2
- COL9A2 | c.1008G>A p.A336= | Splice Region (SNP) | VAF 94/104 reads (90%) | catalogued as rs760647943, COSV65608037; called by muse, mutect2, varscan2
- COLEC12 | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV68370366; called by muse, mutect2, varscan2
- CSMD3 | c.10158A>T p.Q3386H (on ENST00000297405 / NM_001363185.1; = p.Q3217H on NM_052900.3) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV52299752; called by muse, mutect2, varscan2
- CTNNBIP1 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as rs1442815862, COSV65962019; called by muse, mutect2, varscan2
- DMD | c.5818G>A p.G1940R | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV63787342; called by muse, mutect2, varscan2
- DMPK | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.019); catalogued as rs758089399, COSV52176220; called by muse, mutect2
- EFHB | c.1993C>T p.L665F | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1332360038, COSV55552797; called by muse, mutect2, varscan2
- FOXN3 | c.874C>T p.R292W (on ENST00000261302; = p.R270W on NM_005197.4) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs142179906, COSV54315637; called by muse, mutect2, varscan2
- FRMD6 | c.515A>G p.H172R (on ENST00000344768 / NM_001267046.2; = p.H164R on NM_152330.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1340756063, COSV61090536; called by muse, mutect2, varscan2
- HOXC13 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as rs1361579640, COSV54499762; called by muse, mutect2, varscan2
- HTR1F | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV60391038; called by muse, mutect2, varscan2
- INTS1 | c.6356C>T p.A2119V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV67179486; called by muse, mutect2, varscan2
- INTS14 | c.1305G>A p.K435= (on ENST00000313182 / NM_001366360.2; = p.K356= on NM_001136043.3 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 51/136 reads (38%) | catalogued as COSV56012606; called by muse, mutect2, varscan2
- IPO7 | c.2248A>G p.K750E | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV65686871; called by muse, mutect2, varscan2
- KLHL4 | c.1713-1G>T p.X571_splice | Splice Site (SNP) | VAF 18/71 reads (25%) | catalogued as COSV64147246; called by muse, mutect2, varscan2
- LDHAL6B | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.626); catalogued as rs776135267, COSV55694385; called by muse, mutect2, varscan2
- LHFPL1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64334110; called by muse, mutect2, varscan2
- LSG1 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs375975830; called by muse, mutect2, varscan2
- MEGF8 | c.7243G>A p.D2415N (on ENST00000251268 / NM_001271938.2; = p.D2348N on NM_001410.3) | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV52099630; called by muse, mutect2, varscan2
- MSANTD1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs867466019, COSV70873336; called by muse, mutect2, varscan2
- NF1 | c.3406C>T p.R1136W | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1341314304, COSV62192633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4A5 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as COSV60524437; called by muse, mutect2, varscan2
- OR9G4 | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV57249722; called by muse, mutect2, varscan2
- ORM1 | c.414_416del p.K138del | In Frame Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs1211545276; called by pindel, varscan2
- PCDHGB6 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs530193346, COSV53991618; called by muse, mutect2, varscan2
- PKD1L1 | c.5674T>C p.F1892L | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56976496; called by muse, mutect2, varscan2
- PLG | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51986057; called by muse, mutect2
- PNLIPRP3 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 90/98 reads (92%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV65049530; called by muse, mutect2
- POLE | c.4624G>T p.G1542C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV57689321; called by muse, mutect2, varscan2
- PREX1 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs769075228, COSV64256234; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.794G>A p.R265K (on ENST00000421990 / NM_001136042.2; = p.R247K on NM_025267.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV64184392; called by muse, mutect2
- PTPRT | c.3925G>T p.D1309Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62013834, COSV62021981; called by muse, mutect2, varscan2
- RC3H1 | c.2921A>T p.N974I | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV51214568; called by muse, mutect2, varscan2
- RP1L1 | c.6293C>T p.S2098L | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as COSV66759597; called by muse, mutect2, varscan2
- RTEL1 | c.3488C>T p.A1163V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV53929076; called by muse, mutect2, varscan2
- RYR1 | c.8150C>T p.A2717V | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as rs758551300, COSV62109096; called by muse, mutect2, varscan2
- SEL1L2 | c.549+1G>A p.X183_splice | Splice Site (SNP) | VAF 27/111 reads (24%) | catalogued as rs752284504, COSV53157334; called by muse, mutect2, varscan2
- SIK2 | c.243A>T p.K81N | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59255700; called by muse, mutect2, varscan2
- SLC25A21 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58730812; called by muse, mutect2, varscan2
- SLC35A4 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as rs748634741, COSV60052325; called by muse, mutect2, varscan2
- SLC6A2 | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54922619; called by muse, mutect2, varscan2
- SP1 | c.2011G>A p.D671N (on ENST00000327443 / NM_138473.3; = p.D664N on NM_003109.1) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1347724272, COSV59405022; called by muse, mutect2, varscan2
- TP73 | c.367G>T p.G123* | Nonsense Mutation (SNP) | VAF 121/131 reads (92%) | catalogued as COSV60705592; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3161G>A p.G1054D | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.617); catalogued as COSV51959829; called by muse, mutect2, varscan2
- USP43 | c.3236C>A p.A1079D | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV53306503; called by muse, mutect2, varscan2
- USP48 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 185/207 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs765982927, COSV57607693; called by muse, mutect2, varscan2
- WNK1 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM153809, COSV100265781; called by muse, mutect2, varscan2
- BCL2L11 | c.552dup p.R185Tfs*80 (on ENST00000393256 / NM_138621.5; = p.R125Tfs*80 on NM_006538.5) | Frame Shift Ins (INS) | VAF 38/83 reads (46%) | called by mutect2, pindel, varscan2
- SLC10A2 | c.609_615dup p.V206Pfs*43 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- BCOR | c.4062C>T p.S1354= (on ENST00000378444 / NM_001123385.2; = p.S1320= on NM_017745.6) | Silent (SNP) | VAF 121/379 reads (32%) | catalogued as rs747055096, COSV100652652; ClinVar: benign; called by muse, mutect2, varscan2
- CHRND | c.682C>T p.L228= | Silent (SNP) | VAF 57/115 reads (50%) | catalogued as COSV51329893; called by muse, mutect2, varscan2
- CNTNAP4 | c.783C>T p.L261= | Silent (SNP) | VAF 50/97 reads (52%) | catalogued as COSV56698049; called by muse, mutect2, varscan2
- CSF2RB | c.1293G>A p.A431= | Silent (SNP) | VAF 64/142 reads (45%) | catalogued as rs764949392, COSV53260617; called by muse, mutect2
- DAPP1 | c.399G>A p.V133= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV56453372; called by muse, mutect2, varscan2
- DGKI | c.1026G>A p.K342= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs773697170, COSV55972524; called by muse, mutect2, varscan2
- FAM163B | c.306C>T p.F102= | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- FCGR3B | c.288C>T p.L96= | Silent (SNP) | VAF 78/105 reads (74%) | catalogued as COSV54208849, COSV99670318; called by muse, mutect2, varscan2
- KCNJ11 | c.984G>A p.V328= | Silent (SNP) | VAF 92/193 reads (48%) | catalogued as COSV60594082; called by muse, mutect2, varscan2
- KCNS1 | c.1093C>T p.L365= | Silent (SNP) | VAF 64/186 reads (34%) | catalogued as COSV60260959; called by muse, mutect2, varscan2
- KLHL15 | c.1428C>T p.Y476= | Silent (SNP) | VAF 49/164 reads (30%) | catalogued as rs752100343, COSV60141408; called by muse, mutect2, varscan2
- MMP14 | c.876G>A p.K292= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs1360991177, COSV61289422; called by muse, mutect2, varscan2
- NR1H3 | c.865C>T p.L289= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs1174430504, COSV68008818; called by muse, mutect2, varscan2
- OR4A5 | c.93C>G p.L31= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV60524446; called by muse, mutect2, varscan2
- PCDHGA1 | c.834G>A p.T278= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs115965295; called by muse, mutect2, varscan2
- PTPRG | c.219G>A p.T73= | Silent (SNP) | VAF 78/171 reads (46%) | catalogued as rs187568366, COSV55649861; called by muse, mutect2, varscan2
- RBPJL | c.1128G>A p.A376= | Silent (SNP) | VAF 62/182 reads (34%) | catalogued as rs1471952287, COSV59213930, COSV59215556; called by muse, mutect2, varscan2
- RIMS2 | c.99G>A p.T33= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as rs866013254, COSV68498472; called by muse, mutect2, varscan2
- RTN2 | c.597G>A p.S199= | Silent (SNP) | VAF 54/109 reads (50%) | catalogued as rs764702354, COSV55595836; called by muse, mutect2, varscan2
- SMCR8 | c.618G>A p.R206= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV58180712; called by muse, mutect2, varscan2
- TRPT1 | c.165C>T p.F55= (on ENST00000317459 / NM_001160393.1; = p.F6= on NM_031472.4) | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs765307081, COSV54175559; called by muse, mutect2, varscan2
- ZNF770 | c.342C>T p.V114= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV62544914; called by muse, mutect2, varscan2
